Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5507, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5507-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 8.85. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals: poorly-differentiated prostatic adenocarcinoma, Gleason score 4+3 = 7 in the left apex, left base, right apex, right mid and right base of the prostate and poorly-differentiated prostatic adenocarcinoma, Gleason score 3+4 = 7 in the left mid of the prostate. The patient also has a history of a [REDACTED].
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

TCGA-EJ-5507**ADDENDA:****Addendum**

Specimen labeled "right pedicle margin" has been evaluated with multiple levels and PSA, racemase, CK903 and p63 immunohistochemical stains.

The immunohistochemical stains show PSA expression in the glands, confirming prostatic origin. Immunohistochemical stains show expression of racemase in these glands. Presence of basal cells is confirmed by CK903 and p63 immunohistochemical stains.

This immunohistochemical profile suggests these glands represent high grade prostatic intraepithelial neoplasia. No evidence of invasive carcinoma is seen.

FINAL DIAGNOSIS:**PART 1:**

LYMPH NODES, RIGHT PELVIC, EXCISION -

- A. METASTATIC CARCINOMA IN 1 OF 13 LYMPH NODES (1/13).
- B. EXTRANODAL EXTENSION IS PRESENT.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

METASTATIC CARCINOMA IN 1 OF 8 LYMPH NODES (1/8).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE 4 + 5 = 9.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2 CM IN ONE HISTOLOGIC SECTION (SLIDE 3U).
- C. THE CARCINOMA INVOLVES 35% OF THE EXAMINED PROSTATE VOLUME.
- D. EXTENSIVE EXTRAPROSTATIC EXTENSION IS PRESENT.
- E. BILATERAL SEMINAL VESICLES ARE INVOLVED BY CARCINOMA.
- F. THE INKED MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- G. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- H. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- I. PATHOLOGIC TNM STAGE: pT3b N1 MX.
- J. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

PART 4:

RIGHT PEDICLE MARGIN, BIOPSY-

- A. FIBROVASCULAR TISSUE, WITH PROMINENT CRUSH ARTIFACT, AND FOCAL ATYPICAL AREAS.
- B. IMMUNOHISTOCHEMICAL STAINS PENDING, REPORT TO FOLLOW IN AN ADDENDUM.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 8.85
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	95%
WEIGHT OF PROSTATE:	41.11gm
TUMOR SIZE:	Maximum dimension: 2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Unknown
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	NA
LYMPH NODES EXAMINED:	21
LYMPH NODES POSITIVE:	2
EXTRANODAL EXTENSION:	Yes
SIZE OF NODAL METASTASIS:	1.5mm
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file d846e34d-0df1-4584-839f-c8a95780b9c2 (TCGA-EJ-5507.153DE441-FBE9-4C8B-9A84-9CDF9C5EDCF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).